Somatic mutation profile of tumor specimen HTMCP-03-06-02389-01A (aliquot HTMCP-03-06-02389-01A-01D-10409) from CGCI case HTMCP-03-06-02389, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 41.1 years (15,002 days).
Specimen HTMCP-03-06-02389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7105b389-ef99-44ff-afcb-e67a438b2df0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02389-10A (Blood Derived Normal), aliquot HTMCP-03-06-02389-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27aed964-5af3-400a-b244-bddad7f5f91e

The open-access MAF lists 47 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Nonsense Mutation 4, In Frame Del 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2833C>T p.Q945* (on ENST00000404938 / NM_001163941.2; = p.Q500* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as COSV51702560, COSV51711985; called by muse, mutect2, varscan2
- ANKRD30B | c.2941T>A p.F981I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100271700; called by mutect2, varscan2
- CDH7 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as rs751425143, COSV59886742; called by muse, mutect2, varscan2
- CFAP46 | c.6542G>A p.R2181H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs368826118; called by mutect2, varscan2
- KLHL13 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53244693; called by muse, mutect2, varscan2
- MAPK4 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 33/65 reads (51%) | catalogued as rs372835108; called by muse, mutect2, varscan2
- PCDHGA8 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.024); catalogued as rs374049261; called by muse, mutect2, varscan2
- PLXNA3 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1484671509; called by muse, mutect2, varscan2
- RAVER2 | c.1238C>T p.S413F (on ENST00000294428 / NM_001366165.1; = p.S400F on NM_018211.4) | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs1469865854; called by muse, mutect2, varscan2
- RIN2 | c.863C>T p.S288F (on ENST00000255006 / NM_001242581.1; = p.S239F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs941789764; called by muse, mutect2, varscan2
- SPTBN1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1167413670, COSV61688032; called by muse, mutect2, varscan2
- SPTBN1 | c.3127G>A p.V1043M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs768447926, COSV100441856, COSV61685005; called by muse, mutect2, varscan2
- SVEP1 | c.6841G>A p.E2281K | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.492); catalogued as rs749125952; called by muse, mutect2, varscan2
- SYDE2 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 32/182 reads (18%) | catalogued as rs768611054, COSV52318935; called by muse, mutect2, varscan2
- TARS3 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs143111392; called by muse, mutect2, varscan2
- TNIK | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52677986; called by muse, mutect2, varscan2
- ZNF366 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV59219464; called by muse, mutect2, varscan2
- ADCY1 | c.1405C>G p.H469D | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CDH12 | c.1891G>C p.V631L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CLASRP | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COL3A1 | c.3728G>C p.G1243A | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DAP3 | c.203_211del p.Y68_I70del | In Frame Del (DEL) | VAF 34/151 reads (23%) | called by mutect2, pindel, varscan2
- FOXO3 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH2 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- KAT6B | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KCNA1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MDC1 | c.72G>C p.L24F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PDE1C | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- RGL2 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLCO5A1 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- TOP2A | c.282_283dup p.N95Tfs*22 | Frame Shift Ins (INS) | VAF 38/108 reads (35%) | called by mutect2, pindel, varscan2
- TTN | c.85285_85289del p.K28429* (on ENST00000591111; = p.K21005* on NM_003319.4) | Frame Shift Del (DEL) | VAF 100/231 reads (43%) | called by pindel, varscan2
- ZNF366 | c.1328A>G p.H443R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- BAZ1A | c.1659C>T p.L553= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs766774746; called by mutect2, varscan2
- COL21A1 | c.1146G>A p.L382= | Silent (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- CPSF1 | c.3618C>T p.I1206= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs782150090; called by muse, mutect2, varscan2
- HIVEP2 | c.2709G>A p.E903= | Silent (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- KCNB2 | c.462A>C p.R154= | Silent (SNP) | VAF 46/215 reads (21%) | called by muse, mutect2, varscan2
- PAX7 | c.180G>T p.V60= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100946954; called by muse, mutect2, varscan2
- PTPRD | c.5418T>G p.T1806= | Silent (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- TENM1 | c.453T>C p.H151= | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- TNS1 | c.1002C>T p.I334= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs776300904, COSV50690928; called by mutect2, varscan2
- USP19 | c.1572C>T p.F524= | Silent (SNP) | VAF 70/192 reads (36%) | called by muse, mutect2, varscan2
- XKR4 | c.453C>T p.F151= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV59325536; called by muse, mutect2
- ZNF880 | c.27C>T p.F9= | Silent (SNP) | VAF 31/139 reads (22%) | called by muse, mutect2, varscan2
- MAN1B1 | c.1254+1700T>C | Intron (SNP) | VAF 122/603 reads (20%) | called by muse, mutect2, varscan2
